FM case AD9088 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/19f19bcb-ab83-4278-949b-bfca2dba7dd9

Female, 62.7 years: Lobular carcinoma, NOS (ICD-O-3 8520/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
